TCGA case TCGA-E1-A7YH — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9f469edb-6b12-4eab-bd6f-9c10034d4cb7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 47 years; Vital status: Dead; Days to death: 2,835 days (7.8 years).

Diagnoses (6)
1. Astrocytoma, anaplastic (the primary disease): ICD-O-3 morphology code: 9401/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 47.8 years (17,465 days); Year of diagnosis: 2005; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,835 days (7.8 years); First symptom longest duration: >=181 Days; First symptom prior to diagnosis: Seizures; Sites of involvement: Brain, Temporal lobe; Supratentorial localization: White Matter.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 45 days; Days to treatment end: 87 days; Treatment dose: 6,000 cGy; Treatment outcome: Stable Disease; Number of fractions: 30.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 45 days; Days to treatment end: 87 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Days to treatment start: 117 days; Days to treatment end: 216 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 222 days; Days to treatment end: 537 days (1.5 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 706 days (1.9 years); Days to treatment end: 752 days (2.1 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 775 days (2.1 years); Days to treatment end: 835 days (2.3 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Bevacizumab; Days to treatment start: 867 days (2.4 years); Days to treatment end: 1,223 days (3.3 years); Treatment outcome: Stable Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Erlotinib; Days to treatment start: 867 days (2.4 years); Days to treatment end: 1,223 days (3.3 years); Treatment outcome: Stable Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Bevacizumab; Days to treatment start: 1,224 days (3.4 years); Days to treatment end: 1,328 days (3.6 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Days to treatment start: 1,345 days (3.7 years); Days to treatment end: 1,627 days (4.5 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis; Steroid Therapy, preoperative.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 49.7 years (18,154 days); Days to diagnosis: 689 days (1.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 49.9 years (18,217 days); Days to diagnosis: 752 days (2.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 50.1 years (18,305 days); Days to diagnosis: 840 days (2.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.
5. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 52.3 years (19,094 days); Days to diagnosis: 1,629 days (4.5 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.
6. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 55.5 years (20,254 days); Days to diagnosis: 2,789 days (7.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.

Follow-up (7 entries)
- Day 17 (prior to adjuvant therapy): Karnofsky performance status: 80.
- Day 689 (post initial treatment): Progression or recurrence: Yes.
- Day 752 (post initial treatment): Progression or recurrence: Yes.
- Day 840 (post initial treatment): Progression or recurrence: Yes.
- Day 1,629 (post initial treatment): Progression or recurrence: Yes.
- Day 2,789 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 2,835 days (7.8 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Seizure.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-E1-A7YH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 130 mg.
  Slide TCGA-E1-A7YH-01A-01-TSA: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 90; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-E1-A7YH-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-E1-A7YH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Astrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy; Tumor site: Supratentorial, Temporal Lobe; History seizures: Yes; History headaches: No; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: > 181 Days; History asthma: No; History eczema: No; History neoadjuvant steroid treatment: No; History neoadjuvant medication: Yes; Family history brain tumor: No; Idh1 mutation test indicator: No; Inherited genetic syndrome indicator: No; New tumor event diagnosis indicator: Yes.
- New tumor event, Locoregional procedure: New tumor event surgery: No.
- New tumor event, Metastatic procedure: New tumor event surgery met: No.
- New tumor event: New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 2: Pharmaceutical therapy drug name: Ccnu.
- Drug treatment 4: Pharmaceutical therapy drug name: Temodar; Treatment best response: Clinical Progressive Disease.
- Drug treatment 7: Pharmaceutical therapy drug name: Avastin.
- Drug treatment 8: Pharmaceutical therapy drug name: Avastin; Treatment best response: Clinical Progressive Disease.
- Drug treatment 9: Pharmaceutical therapy drug name: VP-16; Treatment best response: Clinical Progressive Disease.
- Follow-up form 1: Lost to follow-up: No; New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; New tumor event radiation treatment: No; New tumor event surgery met: No.
- Follow-up form 4: Lost to follow-up: No; New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event pharmaceutical treatment: No; New tumor event radiation treatment: No; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,835 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,835 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 689 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-E1-A7YH-01A-11D-A349-01): tumor purity 0.54, ploidy 3.94, whole-genome doublings 1.
